Gene-level copy-number profile of tumor specimen TCGA-DF-A2KR-01A from TCGA case TCGA-DF-A2KR, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3.
Specimen TCGA-DF-A2KR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.273b9927-b093-4071-9163-64b44ea7d4c2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DF-A2KR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 835 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/16acb933-1909-4e2c-a159-cf0aa2fc2266

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,678; copy number 2: 19,362; copy number 3: 18,190; copy number 4: 14,638; copy number 5: 2,552; copy number 6: 1,598; copy number 7: 166; copy number 8: 139; copy number 9: 56; copy number 10: 166; copy number 11: 150; copy number 13: 85; copy number 15: 2; copy number 17: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DF-A2KR-01A-11D-A17U-01): tumor purity 0.78, ploidy 3.07, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,563 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–10,427,617, 163 genes, copy number 5 (broad region; genes not listed).
- chr2:129,063,846–152,649,826, 370 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:156,435,290–161,985,282, 86 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:227,870,083–234,913,384, 174 genes, copy number 5 (broad region; genes not listed).
- chr2:241,188,509–242,160,153, 40 genes, copy number 5: ANO7, HDLBP, SEPTIN2, AC104841.1, AC005104.1, FARP2, AC005104.2, MIR3133, KCTD5P1, STK25, BOK-AS1, BOK, AC133528.1, THAP4, RNA5SP122, ATG4B, DTYMK, ING5, AC114730.3, D2HGDH, AC114730.1, AC114730.2, GAL3ST2, AC131097.1, AC131097.2, NEU4, AC131097.3, PDCD1, RTP5, LINC01237, FAM240C, LINC01238, AC093642.3, AC093642.1, AC093642.6, LINC01880, AC093642.2, LINC01881, CICP10, SEPTIN14P2.
- chr3:109,409,990–122,121,139, 203 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:125,225,669–135,439,888, 248 genes, copy number 5–10 (broad region; genes not listed).
- chr5:41,730,065–51,055,459, 83 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr5:121,040,090–129,033,642, 104 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:113,428,540–113,873,351, 8 genes, copy number 6: LINC02518, AL513123.1, RPS27AP11, LINC02541, FO393415.2, FO393415.1, MARCKS, MROCKI.
- chr6:116,244,187–129,516,566, 153 genes, copy number 5–13 (within-gene range 4–13) (broad region; genes not listed).
- chr7:153,144,313–159,233,377, 93 genes, copy number 5 (broad region; genes not listed).
- chr8:102,864,271–103,002,424, 1 gene, copy number 8 (within-gene range 3–8): MAILR.
- chr8:102,923,371–138,497,261, 414 genes, copy number 5–10 (broad region; genes not listed).
- chr10:28,677,510–46,273,557, 307 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr10:63,110,139–63,658,521, 14 genes, copy number 8: RNU6-543P, AL590502.1, NRBF2, JMJD1C, TATDN1P1, AC022022.2, MIR1296, PRELID1P3, JMJD1C-AS1, AC022022.1, REEP3, AC022387.2, MRPL35P2, AC022387.1.
- chr12:66,767–6,672,069, 176 genes, copy number 6–7 (broad region; genes not listed).
- chr12:22,008,348–71,927,248, 1,202 genes, copy number 6–15 (broad region; genes not listed).
- chr16:56,940,278–69,408,571, 310 genes, copy number 5 (broad region; genes not listed).
- chr20:47,160,838–64,313,132, 414 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,460. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
